Somatic mutation profile of tumor specimen TCGA-10-0931-01A (aliquot TCGA-10-0931-01A-01W-0420-08) from TCGA case TCGA-10-0931, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 44.5 years (16,262 days).
Specimen TCGA-10-0931-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd2e9ff6-0f4e-49fc-a27a-8f89dc0d0419.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-10-0931-11A (Solid Tissue Normal), aliquot TCGA-10-0931-11A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/434cf96f-d4df-41b0-bab2-ee86c738fe99

The open-access MAF lists 49 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Nonsense Mutation 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC1 | c.2693A>G p.N898S | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs762722945, COSV60692570; called by muse, mutect2, varscan2
- ARHGAP44 | c.2389C>T p.H797Y | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); catalogued as COSV99309692; called by muse, mutect2
- BAZ1A | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 34/759 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100701073; called by muse, mutect2
- BMP5 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63705855; called by muse, mutect2, varscan2
- BRD3 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57706028; called by muse, mutect2, varscan2
- BTN2A1 | c.261G>C p.E87D | Missense Mutation (SNP) | VAF 113/280 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV57005894; called by muse, mutect2, varscan2
- CD19 | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV61189472; called by muse, mutect2, varscan2
- DNAH3 | c.6353C>G p.S2118C | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99763953; called by muse, mutect2
- DNAJC9 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54350298; called by muse, mutect2, varscan2
- EPGN | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 15/472 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV100141317; called by muse, mutect2
- EXOC1 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765610018, COSV62121668; called by muse, varscan2
- F2 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377462682, COSV61314662; called by muse, mutect2, varscan2
- GFOD1 | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV64955264; called by muse, mutect2, varscan2
- HOXD12 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV66832885; called by muse, mutect2, varscan2
- LPIN3 | c.448C>G p.P150A | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV64719990; called by muse, mutect2, varscan2
- LRRTM3 | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 37/576 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as COSV100791403; called by muse, mutect2
- MED22 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV59299720; called by muse, mutect2, varscan2
- NSUN6 | c.139T>A p.S47T | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV66035000; called by muse, mutect2, varscan2
- OBSL1 | c.4135T>G p.F1379V | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54705935, COSV54710051; called by muse, mutect2, varscan2
- OR6Q1 | c.893A>T p.N298I | Missense Mutation (SNP) | VAF 120/284 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108972; called by mutect2, varscan2
- PAFAH1B3 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs777799764, COSV50652649; called by muse, mutect2, varscan2
- PDZRN3 | c.1373C>G p.A458G | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99726686; called by muse, mutect2
- PSMC5 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 162/171 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99856126; called by muse, mutect2, varscan2
- RUNX1 | c.508G>A p.V170M (on ENST00000344691 / NM_001001890.3; = p.V197M on NM_001754.5) | Missense Mutation (SNP) | VAF 41/1072 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100276112, COSV55869181; called by muse, mutect2
- SEC61A1 | c.1384G>T p.V462F | Missense Mutation (SNP) | VAF 96/207 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV54577460, COSV54578577; called by muse, mutect2, varscan2
- SLC6A3 | c.1644C>A p.Y548* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV99547652; called by mutect2, varscan2
- SLC7A9 | c.451G>C p.V151L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV50091951; called by muse, mutect2, varscan2
- TAGAP | c.891C>A p.D297E | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as COSV57852919; called by muse, mutect2, varscan2
- TENT4B | c.1891G>C p.E631Q (on ENST00000561678 / NM_001365323.2; = p.E616Q on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.099); catalogued as COSV62549088; called by muse, mutect2, varscan2
- TEX15 | c.67A>G p.I23V (on ENST00000256246; = p.I406V on NM_001350162.2) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as rs1006026338, COSV99820444; called by muse, mutect2
- TSPAN13 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV50439113; called by muse, mutect2, varscan2
- USP29 | c.2155A>T p.K719* | Nonsense Mutation (SNP) | VAF 49/135 reads (36%) | catalogued as COSV54145945; called by muse, mutect2, varscan2
- XRN1 | c.3967G>A p.A1323T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.735); catalogued as rs777533054, COSV53817042; called by muse, mutect2, varscan2
- ZCCHC4 | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57183153; called by muse, varscan2
- ZNF281 | c.2266C>A p.H756N | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV54169357; called by muse, mutect2, varscan2
- DUOX1 | c.2532G>A p.L844= | Silent (SNP) | VAF 35/290 reads (12%) | catalogued as COSV100367489; called by muse, mutect2, varscan2
- FGF3 | c.510C>T p.R170= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV61926702; called by muse, mutect2, varscan2
- GUCY1A1 | c.1566C>G p.V522= | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as COSV99636757; called by muse, mutect2
- LNX1 | c.1425C>T p.A475= (on ENST00000263925 / NM_001126328.3; = p.A379= on NM_032622.2) | Silent (SNP) | VAF 123/273 reads (45%) | catalogued as rs201113367, COSV55790597; called by muse, mutect2, varscan2
- MCTP2 | c.2154C>A p.V718= | Silent (SNP) | VAF 18/451 reads (4%) | catalogued as COSV100751712; called by muse, mutect2
- RBBP7 | c.936C>T p.F312= | Silent (SNP) | VAF 65/183 reads (36%) | catalogued as COSV58113364; called by muse, mutect2, varscan2
- RETN | c.159C>T p.S53= | Silent (SNP) | VAF 147/237 reads (62%) | catalogued as COSV55569298; called by muse, mutect2, varscan2
- SKIL | c.774T>C p.T258= | Silent (SNP) | VAF 103/243 reads (42%) | catalogued as rs902739082, COSV52062258; called by muse, mutect2, varscan2
- SLC43A1 | c.366C>T p.A122= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV53560988; called by mutect2, varscan2
- TLN1 | c.4830C>T p.A1610= | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as rs146656116; called by muse, varscan2
- UBE3B | c.3009C>T p.D1003= | Silent (SNP) | VAF 32/528 reads (6%) | catalogued as rs369171639, COSV100688363; ClinVar: likely benign; called by muse, mutect2
- ZNF195 | c.1764C>G p.T588= (on ENST00000399602 / NM_001130520.3; = p.T516= on NM_007152.5) | Silent (SNP) | VAF 15/293 reads (5%) | catalogued as COSV99137543; called by muse, mutect2
- MIR380 | n.12C>G | RNA (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2
- PTHLH | c.524+1398G>C | Intron (SNP) | VAF 51/197 reads (26%) | catalogued as COSV99570632; called by muse, mutect2, varscan2
